Somatic mutation profile of cancer-model specimen HCM-BROD-1128-C15-85B (3D Organoid, passage 6; aliquot HCM-BROD-1128-C15-85B-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-BROD-1128-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 56.3 years (20,546 days).
Specimen HCM-BROD-1128-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f99b2d06-e82e-40bf-b62b-a158f8e804ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1128-C15-10A (Blood Derived Normal), aliquot HCM-BROD-1128-C15-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cf109bd-37af-4767-bec9-79f333cf4261

The open-access MAF lists 162 somatic variants for this specimen: 97 protein-altering or splice-affecting, 55 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 55, Intron 6, Nonsense Mutation 6, 3'UTR 2, 5'Flank 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 151/527 reads (29%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRA3 | c.3913G>A p.D1305N | Missense Mutation (SNP) | VAF 48/526 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs928853508, COSV51561936; called by muse, mutect2
- ADRA1B | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 43/610 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.958); catalogued as rs1415252154; called by muse, mutect2
- BICRA | c.4211C>T p.T1404M | Missense Mutation (SNP) | VAF 351/1074 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1264919160; called by muse, mutect2, varscan2
- C8B | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 22/269 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as rs756905287, COSV64779151; called by muse, mutect2
- CNGB1 | c.3230G>A p.R1077Q | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs374172975; called by muse, mutect2, varscan2
- CNTNAP3 | c.2865G>T p.E955D | Missense Mutation (SNP) | VAF 35/490 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs1317961518; called by muse, mutect2, varscan2
- CROCC | c.2074G>A p.A692T | Missense Mutation (SNP) | VAF 52/590 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs778887976; called by muse, mutect2
- DBF4 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs13309268, COSV99719292; called by muse, mutect2
- DBNDD2 | c.29T>C p.L10S | Missense Mutation (SNP) | VAF 48/790 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as rs928398906; called by muse, mutect2
- DKK1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 51/572 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs545596036; called by muse, mutect2
- DNAJB4 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs188409967; called by muse, mutect2
- DSE | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 63/493 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs201564300; called by muse, mutect2, varscan2
- EPS15L1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 18/652 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1272025635; called by muse, mutect2
- F9 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 43/253 reads (17%) | catalogued as CM094081, CM940708; called by muse, mutect2, varscan2
- FAM170B | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 112/464 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs775087170, COSV61253338; called by muse, varscan2
- FGFR2 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 121/538 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as rs1041970177; called by muse, mutect2, varscan2
- GBX1 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 96/915 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs1240273534; called by muse, mutect2, varscan2
- H2BC18 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.147); catalogued as COSV100516193; called by muse, mutect2
- IPO8 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as COSV99804659; called by muse, mutect2
- MAGEC1 | c.3325G>T p.D1109Y | Missense Mutation (SNP) | VAF 69/318 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV99596770; called by muse, mutect2, varscan2
- MYOM2 | c.1583T>A p.V528D | Missense Mutation (SNP) | VAF 113/558 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50734375; called by muse, mutect2, varscan2
- OR1F1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 59/489 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs546950482, COSV58961193; called by muse, mutect2, varscan2
- OSBP2 | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs771660831; called by muse, mutect2
- PCLO | c.11817A>T p.Q3939H | Missense Mutation (SNP) | VAF 41/351 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as COSV100428853, COSV61660580, COSV61676960; called by muse, mutect2, varscan2
- PDE10A | c.2091G>T p.W697C | Missense Mutation (SNP) | VAF 46/363 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63102324; called by muse, mutect2, varscan2
- PHF20L1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 32/565 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99620437; called by muse, mutect2
- PLEKHG2 | c.1199G>C p.R400T | Missense Mutation (SNP) | VAF 58/852 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as rs1280005619; called by muse, mutect2
- PRRT1 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 119/851 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52997791; called by muse, mutect2, varscan2
- RIMKLB | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 15/404 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV55236342; called by muse, mutect2
- RPS27A | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 11/312 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99703108; called by muse, mutect2
- RPTN | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 54/663 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs1167555229, COSV60167211; called by muse, mutect2
- SGK2 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 74/827 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.051); catalogued as rs774838630, COSV58314725; called by muse, mutect2
- THRB | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 14/480 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1029651348, COSV99769564; called by muse, mutect2
- TP53BP1 | c.5420A>G p.D1807G | Missense Mutation (SNP) | VAF 89/345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1466930077; called by muse, mutect2, varscan2
- TREM2 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 74/513 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs374248493; called by muse, mutect2, varscan2
- TRPM7 | c.5167A>C p.M1723L | Missense Mutation (SNP) | VAF 19/348 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs766277435, COSV57913279; called by muse, mutect2
- VSTM2B | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 58/614 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59260446; called by muse, mutect2
- WDFY4 | c.3290G>A p.R1097H | Missense Mutation (SNP) | VAF 63/483 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs952804690, COSV57430791; called by muse, mutect2, varscan2
- WRAP73 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 52/630 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs149451409; called by muse, mutect2
- ZNF526 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 67/488 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.254); catalogued as rs754975026; called by muse, mutect2, varscan2
- ABCC2 | c.3748C>G p.Q1250E | Missense Mutation (SNP) | VAF 42/453 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); called by muse, mutect2
- AC008397.2 | c.648C>G p.C216W | Missense Mutation (SNP) | VAF 65/476 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ACTN4 | c.2666C>T p.P889L | Missense Mutation (SNP) | VAF 102/1478 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2
- ADCY8 | c.2546T>A p.V849D | Missense Mutation (SNP) | VAF 36/757 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ADGRV1 | c.4571C>T p.S1524L | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANP32B | c.350G>C p.S117T | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- ATP13A4 | c.1911_1912dup p.T638Rfs*22 | Frame Shift Ins (INS) | VAF 24/228 reads (11%) | called by mutect2, pindel, varscan2
- ATP1A2 | c.1716G>T p.E572D | Missense Mutation (SNP) | VAF 144/567 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP5F1C | c.798G>C p.E266D | Missense Mutation (SNP) | VAF 57/371 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRINP1 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C2orf16 | c.3905A>T p.K1302M | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- CAPN8 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 44/384 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CBLB | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 46/309 reads (15%) | called by muse, mutect2, varscan2
- CCDC146 | c.85C>G p.P29A | Missense Mutation (SNP) | VAF 10/391 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- CCDC83 | c.179G>C p.R60T | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2
- CELF4 | c.1301A>T p.D434V | Missense Mutation (SNP) | VAF 108/430 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CLCN5 | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.816); called by muse, mutect2
- CLSPN | c.3747+1G>T p.X1249_splice | Splice Site (SNP) | VAF 11/399 reads (3%) | called by muse, mutect2
- COL4A1 | c.977G>A p.G326D | Missense Mutation (SNP) | VAF 64/343 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD2 | c.6037T>G p.F2013V | Missense Mutation (SNP) | VAF 49/300 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTNNA1 | c.2362C>T p.H788Y | Missense Mutation (SNP) | VAF 61/476 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- CTSZ | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 137/600 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- CYP2D7 | c.867C>A p.S289R | Missense Mutation (SNP) | VAF 52/506 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- DLL3 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 608/1322 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- DMXL2 | c.8887G>A p.E2963K | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOK5 | c.728A>C p.N243T | Missense Mutation (SNP) | VAF 30/420 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.081); called by muse, mutect2
- DUS2 | c.442A>T p.T148S | Missense Mutation (SNP) | VAF 79/307 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EIF2S3B | c.1169A>G p.K390R | Missense Mutation (SNP) | VAF 194/803 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ESR1 | c.876G>A p.W292* | Nonsense Mutation (SNP) | VAF 117/599 reads (20%) | called by muse, mutect2, varscan2
- FOXG1 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 36/908 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- GAS2L1 | c.722G>C p.S241T | Missense Mutation (SNP) | VAF 37/380 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- GJD4 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 156/763 reads (20%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- GLCCI1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 36/634 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GP6 | c.872G>A p.W291* | Nonsense Mutation (SNP) | VAF 71/630 reads (11%) | called by muse, mutect2, varscan2
- H3C10 | c.338T>C p.I113T | Missense Mutation (SNP) | VAF 30/429 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- HP | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INPP5B | c.1861C>G p.H621D (on ENST00000373023; = p.H541D on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/367 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIPI | c.160T>G p.F54V | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2
- LMTK3 | c.768C>G p.H256Q | Missense Mutation (SNP) | VAF 28/568 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MGAM | c.3259A>C p.I1087L | Missense Mutation (SNP) | VAF 56/513 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- PTPRZ1 | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- QSOX1 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 70/870 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2
- RB1CC1 | c.2543T>C p.I848T | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- RBMS2 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 91/367 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- RIMKLB | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 52/562 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); called by muse, mutect2
- RNF4 | c.52A>T p.K18* | Nonsense Mutation (SNP) | VAF 37/348 reads (11%) | called by muse, mutect2, varscan2
- RPS6KA3 | c.1883A>C p.E628A | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, mutect2
- RRBP1 | c.2341C>T p.R781W (on ENST00000377813 / NM_001365613.2; = p.R348W on NM_004587.3) | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SIGLEC1 | c.4062C>G p.F1354L | Missense Mutation (SNP) | VAF 23/478 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2
- SNTG2 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 35/379 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2
- SORBS1 | c.2732G>A p.G911E (on ENST00000361941 / NM_001034954.2; = p.G561E on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/668 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TAAR6 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 95/471 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- TNN | c.1745A>G p.Q582R | Missense Mutation (SNP) | VAF 48/525 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- ZNF33B | c.1411T>C p.C471R | Missense Mutation (SNP) | VAF 58/441 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF365 | c.725A>T p.E242V | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2
- ZNF763 | c.445C>G p.P149A (on ENST00000358987 / NM_001367172.2; = p.P152A on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ABCA2 | c.6873C>T p.N2291= (on ENST00000614293; = p.N2261= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/486 reads (12%) | catalogued as rs371356634; called by muse, varscan2
- AC127029.3 | c.837C>T p.Y279= | Silent (SNP) | VAF 127/590 reads (22%) | catalogued as rs753659458, COSV60111458; called by muse, mutect2, varscan2
- ACSF3 | c.1395G>A p.Q465= | Silent (SNP) | VAF 47/434 reads (11%) | catalogued as rs1451312853; called by muse, mutect2, varscan2
- AKNA | c.3432A>G p.R1144= | Silent (SNP) | VAF 11/323 reads (3%) | called by muse, mutect2
- ATG7 | c.108C>T p.N36= | Silent (SNP) | VAF 40/340 reads (12%) | catalogued as rs1029656328; called by muse, varscan2
- BCR | c.3630G>A p.T1210= | Silent (SNP) | VAF 77/580 reads (13%) | catalogued as rs531259855; called by muse, varscan2
- BNIP1 | c.30G>T p.R10= | Silent (SNP) | VAF 58/445 reads (13%) | catalogued as rs768368776; called by muse, mutect2, varscan2
- BRSK1 | c.1632C>T p.V544= | Silent (SNP) | VAF 100/787 reads (13%) | catalogued as rs1188306016; called by muse, mutect2, varscan2
- CBARP | c.900G>A p.P300= (on ENST00000382477; = p.P280= on NM_152769.3) | Silent (SNP) | VAF 34/850 reads (4%) | catalogued as rs938268200; called by muse, mutect2
- CCDC148 | c.1128C>T p.A376= | Silent (SNP) | VAF 15/337 reads (4%) | called by muse, mutect2
- CCNJL | c.36C>T p.A12= | Silent (SNP) | VAF 45/553 reads (8%) | catalogued as rs756623912; called by muse, mutect2
- CLEC14A | c.687C>T p.D229= | Silent (SNP) | VAF 56/507 reads (11%) | catalogued as COSV60561971; called by muse, mutect2, varscan2
- CSNK1A1L | c.912A>G p.K304= | Silent (SNP) | VAF 123/552 reads (22%) | called by muse, mutect2, varscan2
- DAB1 | c.1101G>A p.P367= (on ENST00000371231; = p.P334= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 43/570 reads (8%) | catalogued as rs201974535, COSV64691430, COSV64694343; called by muse, mutect2
- DCDC2C | c.267C>T p.R89= | Silent (SNP) | VAF 76/562 reads (14%) | catalogued as rs1157942453; called by muse, mutect2, varscan2
- DCHS2 | c.261C>T p.R87= | Silent (SNP) | VAF 241/676 reads (36%) | catalogued as COSV100251985; called by muse, mutect2, varscan2
- FAT1 | c.1257C>A p.L419= | Silent (SNP) | VAF 28/322 reads (9%) | catalogued as COSV71671618; called by muse, mutect2
- FNDC11 | c.309C>T p.I103= | Silent (SNP) | VAF 54/1036 reads (5%) | catalogued as rs200404643; called by muse, mutect2
- GRAMD2B | c.741C>T p.F247= | Silent (SNP) | VAF 36/358 reads (10%) | called by muse, mutect2
- HJV | c.303C>T p.L101= | Silent (SNP) | VAF 92/1018 reads (9%) | called by muse, mutect2
- HMCN1 | c.12489C>A p.L4163= | Silent (SNP) | VAF 18/288 reads (6%) | called by muse, mutect2
- HOXD9 | c.132C>T p.G44= | Silent (SNP) | VAF 82/878 reads (9%) | catalogued as rs1426870162, COSV50890666; called by muse, mutect2
- HS3ST5 | c.468C>T p.S156= | Silent (SNP) | VAF 64/379 reads (17%) | called by muse, mutect2, varscan2
- IFNW1 | c.450C>A p.I150= | Silent (SNP) | VAF 20/288 reads (7%) | called by muse, mutect2
- IGHV3-13 | c.288C>T p.S96= | Silent (SNP) | VAF 29/253 reads (11%) | catalogued as rs1555437082; called by muse, mutect2, varscan2
- IQCM | c.1011T>C p.R337= | Silent (SNP) | VAF 42/346 reads (12%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.1353A>G p.S451= | Silent (SNP) | VAF 49/495 reads (10%) | called by muse, mutect2
- KCNG1 | c.1029C>T p.R343= | Silent (SNP) | VAF 73/943 reads (8%) | catalogued as rs772473814, COSV65370332; called by muse, mutect2
- LRRC38 | c.30C>T p.A10= | Silent (SNP) | VAF 34/410 reads (8%) | called by muse, mutect2
- MARK4 | c.1107G>A p.R369= | Silent (SNP) | VAF 63/722 reads (9%) | called by muse, mutect2
- MRPL2 | c.885C>T p.Y295= | Silent (SNP) | VAF 40/407 reads (10%) | catalogued as rs1299707479; called by muse, mutect2, varscan2
- MYH4 | c.3682C>T p.L1228= | Silent (SNP) | VAF 49/394 reads (12%) | catalogued as COSV99701674; called by muse, mutect2, varscan2
- NBAS | c.297G>A p.K99= | Silent (SNP) | VAF 32/382 reads (8%) | catalogued as rs773207325; called by muse, mutect2
- NDUFS6 | c.258G>A p.A86= | Silent (SNP) | VAF 73/734 reads (10%) | catalogued as rs758741439; called by muse, mutect2, varscan2
- NKPD1 | c.1381C>T p.L461= | Silent (SNP) | VAF 151/1194 reads (13%) | called by muse, mutect2, varscan2
- NOL4L | c.225G>A p.K75= | Silent (SNP) | VAF 167/990 reads (17%) | called by muse, mutect2, varscan2
- OLIG1 | c.741C>T p.C247= | Silent (SNP) | VAF 71/404 reads (18%) | called by muse, mutect2, varscan2
- OR2V2 | c.366C>T p.D122= | Silent (SNP) | VAF 54/466 reads (12%) | catalogued as rs1218364415; called by muse, mutect2, varscan2
- OR9H1P | c.720T>A p.A240= | Silent (SNP) | VAF 89/392 reads (23%) | called by muse, mutect2, varscan2
- PKD2 | c.2586C>T p.A862= | Silent (SNP) | VAF 59/385 reads (15%) | catalogued as rs373043298; ClinVar: likely benign; called by muse, mutect2, varscan2
- PKHD1 | c.3453G>A p.P1151= | Silent (SNP) | VAF 42/633 reads (7%) | catalogued as COSV61878001; called by muse, mutect2
- PNCK | c.567C>T p.Y189= (on ENST00000340888 / NM_001366975.1; = p.Y272= on NM_001039582.3) | Silent (SNP) | VAF 172/449 reads (38%) | catalogued as rs377279617, COSV100562314; called by muse, mutect2, varscan2
- POLRMT | c.2412C>T p.G804= | Silent (SNP) | VAF 30/867 reads (3%) | called by muse, mutect2
- PPP2R2C | c.849C>T p.S283= | Silent (SNP) | VAF 47/510 reads (9%) | catalogued as rs771757681, COSV59446130; called by muse, mutect2
- PTN | c.75A>T p.A25= | Silent (SNP) | VAF 75/273 reads (27%) | called by muse, mutect2, varscan2
- PTPN5 | c.570C>A p.S190= | Silent (SNP) | VAF 62/521 reads (12%) | called by muse, mutect2, varscan2
- RASGRP1 | c.756C>T p.N252= | Silent (SNP) | VAF 56/410 reads (14%) | catalogued as rs36111378, COSV60363503; called by muse, mutect2, varscan2
- RFX3 | c.783T>G p.P261= | Silent (SNP) | VAF 14/377 reads (4%) | called by muse, mutect2
- SALL3 | c.1767C>T p.G589= | Silent (SNP) | VAF 86/884 reads (10%) | catalogued as rs745938058; called by muse, mutect2, varscan2
- SETDB1 | c.1563G>T p.G521= | Silent (SNP) | VAF 91/322 reads (28%) | called by muse, mutect2, varscan2
- SF3B1 | c.2016T>C p.A672= | Silent (SNP) | VAF 77/392 reads (20%) | called by muse, mutect2, varscan2
- SHANK2 | c.90A>G p.E30= | Silent (SNP) | VAF 82/1948 reads (4%) | called by muse, mutect2
- SOGA3 | c.486G>A p.P162= | Silent (SNP) | VAF 69/620 reads (11%) | catalogued as rs932561812; called by muse, mutect2, varscan2
- TMEM271 | c.150C>T p.G50= | Silent (SNP) | VAF 99/775 reads (13%) | called by muse, mutect2, varscan2
- TNFRSF10C | c.312C>A p.T104= | Silent (SNP) | VAF 71/248 reads (29%) | called by muse, mutect2, varscan2
- ABHD17A | c.332+315G>A | Intron (SNP) | VAF 56/501 reads (11%) | called by muse, mutect2, varscan2
- CCL7 | c.77-10T>C | Intron (SNP) | VAF 52/598 reads (9%) | called by muse, mutect2
- DLG1 | c.483+10632G>A | Intron (SNP) | VAF 26/236 reads (11%) | called by muse, mutect2, varscan2
- FGFR3 | c.*1469C>T | 3'UTR (SNP) | VAF 91/613 reads (15%) | catalogued as rs369758941; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNMA1 | c.378+268C>T | Intron (SNP) | VAF 56/596 reads (9%) | called by muse, mutect2
- KCNQ1 | c.1394-15279G>A | Intron (SNP) | VAF 47/367 reads (13%) | catalogued as rs1383065992; called by muse, mutect2, varscan2
- MMD2 | c.*910C>A | 3'UTR (SNP) | VAF 52/496 reads (10%) | called by muse, mutect2, varscan2
- NRG1 | chr8:31640008 C>A | 5'Flank (SNP) | VAF 22/372 reads (6%) | called by muse, mutect2
- PAXIP1 | chr7:155004062 G>A | 5'Flank (SNP) | VAF 42/535 reads (8%) | called by muse, mutect2
- TTN | c.10360+3944A>C | Intron (SNP) | VAF 53/219 reads (24%) | called by muse, mutect2, varscan2
